MMRF case MMRF_1759 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d05e06fa-4591-4753-bf8c-d735eb6058a3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 76.1 years (27,809 days); ISS stage: II; Days to last known disease status: 747 days (2.0 years); Days to last follow up: 747 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 507 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 507 days (1.4 years); Days to treatment end: 714 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 741 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 4.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.489 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.6 mg/dL; Immunoglobulin G 48.5 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 4.69 µg/mL; Lactate Dehydrogenase 8.03 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 9.7 g/dL; Glucose 4.68 mmol/L.
- Day 86 (ECOG 1): M Protein 0.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 4.32 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 5.17 mmol/L.
- Day 170 (ECOG 1): M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 5.6 g/dL; Glucose 5.83 mmol/L.
- Day 263 (ECOG 1): M Protein 0.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.24 mmol/L.
- Day 747 (ECOG 1): M Protein 1.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.978 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.54 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.288 g/L; Immunoglobulin M 0.182 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 3.8 mmol/L.

Other clinical attributes
- Day -5: Weight: 68 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.

Biospecimens (2 samples)
- Sample MMRF_1759_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1759_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
